Gene-level copy-number profile of tumor specimen TCGA-A2-A0SV-01A from TCGA case TCGA-A2-A0SV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.3 years (23,126 days).
Specimen TCGA-A2-A0SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.438bf0f6-af07-42dd-8121-fce6c1163e97.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0SV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce494b66-86f7-41d0-8e1c-36706ff9dd59

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 13,372; copy number 2: 40,142; copy number 3: 2,193; copy number 4: 2,248; copy number 5: 1,537; copy number 6: 60; copy number 7: 4; copy number 8: 104; copy number 10: 65; copy number 12: 4; copy number 14: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0SV-01A-11D-A087-01): tumor purity 0.63, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:29,795,938–29,983,114, 5 genes: AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr7:159,231,435–159,233,377, 1 gene: PIP5K1P2.
- chr21:10,328,411–14,144,468, 53 genes: AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2.
- chr21:14,143,581–14,144,158, 1 gene: ERLEC1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,793 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:4,012,708–4,041,764, 2 genes, copy number 7: AC025773.1, AC025187.1.
- chr5:34,164,698–37,753,435, 59 genes, copy number 6 (within-gene range 1–6): AC138409.2, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P.
- chr8:37,326,575–41,650,817, 106 genes, copy number 5–8 (broad region; genes not listed).
- chr8:41,660,441–41,665,566, 3 genes, copy number 5: MIR486-1, MIR486-2, AC113133.1.
- chr8:46,549,089–141,432,454, 1,355 genes, copy number 5 (broad region; genes not listed).
- chr8:141,434,545–141,437,954, 1 gene, copy number 5: AC100803.4.
- chr8:141,968,091–145,066,685, 170 genes, copy number 5 (broad region; genes not listed).
- chr19:30,553,956–30,668,647, 2 genes, copy number 7: AC011504.1, AC011478.1.
- chr20:53,255,979–54,269,542, 19 genes, copy number 14 (within-gene range 2–14): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:57,599,695–61,940,617, 76 genes, copy number 6–12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
